Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5117, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5117-01A (Primary Tumor).

FINAL DIAGNOSIS

KIDNEY, RIGHT, NEPHRECTOMY -

- A. RENAL CELL CARCINOMA, CHROMOPHOBE TYPE.
- B. FUHRMAN NUCLEAR GRADE IS 2/3.
- C. THE GREATEST DIAMETER OF THE NEOPLASM IS 4.9 cm.
- D. THE NEOPLASM IS CONFINED WITHIN THE RENAL CAPSULE.
- E. NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- F. ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- G. ALL SURGICAL MARGINS ARE FREE OF THE NEOPLASM.
- H. THE NON-NEOPLASTIC KIDNEY WITH FOCAL GLOMERULOSCLEROSIS AND INTERSTITIAL INFLAMMATION.
- I. TNM STAGE: PT1b NX MX.

Source: NCI Genomic Data Commons file 9c860240-ec13-47ed-b54a-f421ae73913e (TCGA-B0-5117.7FEB1067-CA6C-4B22-A63D-D2DA4CF0F55A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).